Surgical pathology report (de-identified scan), TCGA case TCGA-16-1063, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1063-01B (Primary Tumor).

[page 1 of 2]
S

16-1063

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: M
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Surgical Service
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Soft-Tissue: brain tumour

OTHER CASE NUMBERS

DIAGNOSIS

1. Brain tumor, site unspecified:
-Glioblastoma with areas of oligodendrocytic differentiation.

COMMENT

The 1p19q mutation status will be reported in the addendum.

GROSS DESCRIPTION

1. The specimen labeled with the patient's name and as "Soft-Tissue: brain tumor". Contains multiple irregularly shaped fragments of pink-tan, focally hemorrhagic, soft tissue; received in 10% buffered formalin. In aggregate this measures 4.0 x 3.0 x 1.7 cm and weighs 7.0 g (post formalin fixation).

1A-1E representative sections submitted

MICROSCOPIC DESCRIPTION

Sections show a glioblastoma multiforme with vascular proliferation, atypia and frequent mitoses. An admixed oligodendrocytic component is

[page 2 of 2]
es

16-1063

Patient Name: [REDACTED]

MRN: [REDACTED]

Gender: M

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Surgical Service

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected [REDACTED]

Resulted: [REDACTED]

present in most sections. In the most astrocytic areas of the tumor, the GFAP is positive in the majority, but not all cells. P53 is positive in 5-10% of the cells. MIB is positive in 10-20% of the cells.

Molecular Diagnostics Status: Ordered

Source: NCI Genomic Data Commons file bc7a156d-62c3-4bcc-b70b-e30bdd4ea4ca (TCGA-16-1063.E2C15E1D-CB5C-425F-8081-2FD6484D4846.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).